Gene-level copy-number profile of specimen HCM-BROD-0225-C43-85M from HCMI case HCM-BROD-0225-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.8 years (15,646 days).
Specimen HCM-BROD-0225-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0cd79a9a-1e8d-4566-8570-113456694612.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0225-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/07f35171-c2a9-4df2-b7c7-20bf797d965c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,031; copy number 2: 55,855; copy number 3: 1; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:188,978,092–188,978,161, 2 genes (within-gene range 0–1): MIR1245A, MIR1245B.
- chr2:215,436,253–215,436,992, 1 gene: AC012462.3.
- chr7:94,278,680–94,431,227, 2 genes: AC002074.1, COL1A2.
- chr11:65,423,273–65,424,118, 3 genes: AP000944.4, AP000944.3, AP000944.2.
- chr11:65,497,688–65,506,516, 4 genes: MALAT1, AP000769.2, AP000769.5, AP000769.3.
- chr14:61,695,513–61,751,099, 2 genes (within-gene range 0–2): HIF1A, HIF1A-AS3.
- chr17:59,841,266–59,847,544, 2 genes (within-gene range 0–1): MIR21, RNU6-450P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
